MMRF case MMRF_1981 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/28830b86-bd3d-4a7d-a477-e561ce92d531

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.5 years (23,187 days); ISS stage: III; Days to last known disease status: 995 days (2.7 years); Days to last follow up: 995 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 39 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 76 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 101 days; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 126 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,022 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 621 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.514 mg/dL; Immunoglobulin G 5.97 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 10.1 µg/mL; Lactate Dehydrogenase 5.93 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 234 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.72 mmol/L.
- Day 78 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.796 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 2.14 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 180 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 7.92 mmol/L.
- Day 253 (ECOG 2): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 2 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6 mmol/L.
- Day 407 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.793 mg/dL; Immunoglobulin G 6.6 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 1.62 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 5.83 mmol/L.
- Day 484 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 7.65 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.93 g/L; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 5.89 mmol/L.
- Day 582 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 9.57 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 1.16 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 645 (ECOG 2): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.49 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 1.39 g/L; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 416 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.82 mmol/L.
- Day 707 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.99 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 806 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 7.43 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.9 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.35 mmol/L; Albumin 47 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.
- Day 897 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 6.53 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.84 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 135 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 995 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.894 mg/dL; Immunoglobulin G 6.36 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.81 g/L; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -4: Weight: 96 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1981_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1981_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
